Somatic mutation profile of tumor specimen RC-B6SE-TTP1-A (aliquot RC-B6SE-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SE, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 58.3 years (21,302 days).
Specimen RC-B6SE-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63dddd32-fd53-471a-b3a0-6783b3277a9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SE-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SE-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd04f310-43a4-4920-b2a2-bbf050eda603

The open-access MAF lists 319 somatic variants for this specimen: 217 protein-altering or splice-affecting, 81 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 81, Nonsense Mutation 9, 5'Flank 5, Frame Shift Del 4, 3'UTR 4, RNA 4, 5'UTR 4, Intron 3, 3'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOD2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104895461, CM012823, COSV56049453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNFAIP3 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 18/205 reads (9%) | catalogued as rs864321626, CM160203, COSV52796831; ClinVar: pathogenic; called by muse, mutect2
- USH2A | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs527236139, CM148283, COSV56321550; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2
- ABCA2 | c.3281G>A p.R1094H (on ENST00000614293; = p.R1064H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688118; called by muse, mutect2
- ADCY6 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1476068864; called by muse, mutect2, varscan2
- AGAP1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1288473351, COSV58318298; called by muse, mutect2
- AGAP1 | c.2171C>T p.P724L (on ENST00000304032 / NM_001037131.3; = p.P671L on NM_014914.5) | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746826800; called by muse, mutect2, varscan2
- AKNA | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 52/299 reads (17%) | catalogued as COSV99800119; called by muse, mutect2, varscan2
- ALOX12 | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs866609091; called by muse, mutect2, varscan2
- ALS2CL | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as rs756342748, COSV59670131; called by muse, mutect2, varscan2
- ANO9 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs750658238, COSV60451453; called by muse, mutect2
- AP3B2 | c.2128G>C p.G710R | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs377674537, COSV99916076; called by muse, mutect2, varscan2
- ARHGEF10 | c.2906G>A p.R969H (on ENST00000398564; = p.R944H on NM_014629.4) | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs766200020, COSV100035270; called by muse, mutect2
- ARMC8 | c.35G>C p.S12T | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.878); catalogued as COSV61768937; called by muse, mutect2, varscan2
- ATP1A2 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746383817, CM105887, COSV63402315; called by muse, mutect2, varscan2
- ATP2B2 | c.2177C>T p.T726M (on ENST00000352432; = p.T692M on NM_001683.5) | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421091853; called by muse, mutect2, varscan2
- B3GNT3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752385665, COSV59438987; called by muse, mutect2, varscan2
- BAZ2B | c.3977G>A p.G1326E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as rs1199320032; called by muse, mutect2, varscan2
- BCL7A | c.43A>C p.K15Q | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV55850131; called by muse, mutect2
- BDKRB2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240626421; called by muse, mutect2
- BSN | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs376181418, COSV56517028; called by muse, mutect2, varscan2
- CACNA1E | c.5795G>A p.R1932Q | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as rs759385572, COSV100703105; called by muse, mutect2, varscan2
- CCDC182 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.013); catalogued as rs1435548240; called by muse, mutect2, varscan2
- CD58 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.066); catalogued as rs754559234, COSV59841737; called by muse, mutect2
- CHST13 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV60042396; called by muse, mutect2
- CLCN1 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.616); catalogued as rs746734545, COSV100578257; called by muse, mutect2, varscan2
- CNKSR3 | c.1643C>T p.T548M | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1166314981, COSV70481574; called by muse, mutect2
- CNNM1 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV63202900; called by muse, mutect2, varscan2
- CPA3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1242938207; called by muse, mutect2
- CSMD3 | c.7865C>T p.A2622V (on ENST00000297405 / NM_001363185.1; = p.A2518V on NM_052900.3) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs752866181, COSV52185717, COSV52240395; called by muse, mutect2, varscan2
- CXCR5 | c.1026T>A p.C342* | Nonsense Mutation (SNP) | VAF 34/263 reads (13%) | catalogued as COSV52684719; called by muse, mutect2, varscan2
- DENND2A | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs763327681, COSV52048213; called by muse, mutect2
- DIRAS2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 35/261 reads (13%) | catalogued as COSV65370662; called by muse, mutect2, varscan2
- DLGAP4 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs1213325065; called by muse, mutect2, varscan2
- DNAH11 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs771256529; called by muse, mutect2, varscan2
- EBF4 | c.1357G>A p.A453T (on ENST00000609451; = p.A449T on NM_001110514.1) | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs1421583996; called by muse, mutect2
- EEF1AKNMT | c.1697G>A p.R566Q (on ENST00000361735 / NM_015935.5; = p.R480Q on NM_014955.3) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs200264969, COSV100675746; called by muse, mutect2
- EGR1 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 29/374 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1296620472, COSV53519164; called by muse, mutect2
- EGR3 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100416171; called by muse, mutect2
- EVX2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57962613; called by muse, mutect2
- FAM135A | c.4063C>G p.L1355V (on ENST00000370479 / NM_001351599.1; = p.L1142V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52047751, COSV52051624; called by muse, mutect2
- FAM71D | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as rs769861811; called by muse, mutect2, varscan2
- FAT3 | c.11695G>A p.G3899S | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs778461689, COSV53144604, COSV99971700; called by muse, mutect2
- FMO3 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs200985584; called by muse, mutect2, varscan2
- FOXS1 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54068006, COSV99640365; called by muse, mutect2
- FTCD | c.958C>G p.R320G | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52429053; called by muse, mutect2, varscan2
- GFY | c.1487C>G p.P496R | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1197678255; called by muse, mutect2
- GMEB2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs370349975; called by muse, mutect2, varscan2
- GPR6 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV51571247, COSV51573087; called by muse, mutect2
- H1-2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs138308559, COSV59190864, COSV59191766; called by muse, mutect2
- H4C9 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 59/472 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as rs759519873; called by muse, mutect2, varscan2
- HGF | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as COSV55949368; called by muse, mutect2
- HS3ST6 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs770429079, COSV53533697; called by muse, mutect2
- IGHG2 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.072); catalogued as rs774006563; called by muse, mutect2, varscan2
- IGLV3-1 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200900019; called by muse, varscan2
- IK | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.969); catalogued as COSV52802158; called by muse, mutect2
- IZUMO2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs1334566025, COSV53231558; called by muse, mutect2, varscan2
- JOSD2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs780599366, COSV65351166; called by muse, mutect2, varscan2
- KIF19 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1294570018; called by muse, mutect2
- KLHL15 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.885); catalogued as rs1445245390; called by muse, mutect2, varscan2
- KLK4 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1568514332, COSV60675658; called by muse, mutect2, varscan2
- KPRP | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.216); catalogued as rs753295469, COSV64221202; called by muse, mutect2
- KRT17 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs564768263, COSV100245236; called by muse, mutect2, varscan2
- LGR4 | c.2846T>C p.V949A | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1388907731; called by muse, mutect2, varscan2
- LPA | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs201102026; called by muse, mutect2, varscan2
- LYPD5 | c.424C>T p.H142Y (on ENST00000377950 / NM_001031749.3; = p.H99Y on NM_182573.2) | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.373); catalogued as rs767089867; called by muse, mutect2
- MAGEC1 | c.2747C>T p.A916V | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776851614, COSV53578740; called by muse, mutect2, varscan2
- MAGI1 | c.3032G>T p.R1011L (on ENST00000402939 / NM_001033057.2; = p.R1040L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58339201; called by muse, varscan2
- MEI1 | c.3626C>T p.S1209L | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs748954338; called by muse, mutect2, varscan2
- MID1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 27/378 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs371028819, CM070996, COSV100452448, COSV58200135; called by muse, mutect2
- MUC16 | c.16607G>A p.R5536Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763953432, COSV67500275; called by muse, mutect2, varscan2
- MYOC | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99231645; called by muse, mutect2
- NCKIPSD | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs143436723; called by muse, mutect2, varscan2
- NEFM | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV55334374; called by muse, mutect2
- NKX2-6 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs1444907797, COSV61492955; called by muse, mutect2
- NLRC5 | c.5219C>T p.P1740L | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs766874677, COSV52654598; called by muse, mutect2, varscan2
- NPIPB3 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749084790; called by mutect2, varscan2
- NR0B1 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 57/501 reads (11%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1363322287; called by muse, mutect2, varscan2
- NTN4 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59218831; called by muse, mutect2, varscan2
- NYAP2 | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV56005652, COSV56016052, COSV99796255; called by muse, mutect2, varscan2
- OR6C6 | c.796G>C p.V266L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV64455888; called by muse, mutect2
- OSR1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55345784; called by muse, mutect2, varscan2
- PAX1 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV68271645; called by muse, mutect2
- PCDHB12 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 60/635 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV53396166; called by muse, mutect2
- PER1 | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs777117943, COSV57921880; called by muse, mutect2, varscan2
- PHACTR3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63036146; called by muse, mutect2, varscan2
- PLEKHD1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs899153016; called by muse, mutect2, varscan2
- PPFIA4 | c.3349C>T p.R1117C (on ENST00000447715; = p.R1118C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99690674; called by muse, mutect2, varscan2
- PPL | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs200334319; called by muse, mutect2
- PSG8 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs762189392, COSV60609526; called by muse, mutect2, varscan2
- PTPRB | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752827762, COSV54240178, COSV99039277; called by muse, mutect2
- RALGAPA2 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV52503481; called by muse, mutect2, varscan2
- RD3L | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1317544803; called by muse, mutect2, varscan2
- ROBO4 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465907946; called by muse, mutect2
- SDK2 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs766963724, COSV101166609; called by muse, mutect2, varscan2
- SEMA6A | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56710026; called by muse, mutect2, varscan2
- SEPHS1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV59259297; called by muse, mutect2
- SEPTIN4 | c.243dup p.S82Lfs*7 | Frame Shift Ins (INS) | VAF 39/388 reads (10%) | catalogued as rs35378753; called by mutect2, pindel
- SETD7 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349071882, COSV56800032; called by muse, mutect2, varscan2
- SEZ6L | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759752155, COSV50660793; called by muse, mutect2, varscan2
- SGK1 | c.77-1G>T p.X26_splice | Splice Site (SNP) | VAF 41/373 reads (11%) | catalogued as COSV52804758; called by muse, mutect2, varscan2
- SHROOM2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1425621471, COSV101098081; called by muse, mutect2, varscan2
- SLC44A1 | c.794A>T p.K265M | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV58265381; called by muse, mutect2, varscan2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, mutect2
- SNAI2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50078625; called by muse, mutect2, varscan2
- SNRK | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765908830; called by muse, mutect2, varscan2
- SOX1 | c.725A>C p.N242T | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.14); catalogued as rs1488703494; called by muse, mutect2, varscan2
- SPINK5 | c.2652G>A p.M884I | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1431258015; ClinVar: uncertain significance; called by muse, mutect2
- SPZ1 | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs754109882; called by muse, mutect2, varscan2
- SQOR | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs764793722; called by muse, mutect2, varscan2
- STAG3 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs747651393; called by muse, mutect2, varscan2
- STARD9 | c.13616G>A p.R4539Q | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs930500379; called by muse, mutect2, varscan2
- STRIP1 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs1217914475; called by muse, mutect2, varscan2
- TAF1C | c.1336C>A p.H446N | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV58988038; called by muse, mutect2, varscan2
- TBX21 | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV51597345; called by muse, mutect2
- TESPA1 | c.767G>C p.W256S (on ENST00000316577 / NM_001098815.3; = p.W118S on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100345217; called by muse, mutect2
- TMEM132B | c.3112G>A p.G1038S | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.977); catalogued as rs1458737441, COSV100170170, COSV100171394; called by muse, mutect2
- TNFRSF14 | c.500del p.P167Rfs*23 | Frame Shift Del (DEL) | VAF 33/281 reads (12%) | catalogued as rs772088410, COSV63185963; called by mutect2, pindel, varscan2
- TNKS1BP1 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376099913; called by muse, mutect2
- TP53BP1 | c.5417C>T p.A1806V | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1157211964, COSV53017747; called by muse, mutect2
- TP63 | c.579G>A p.T193= | Splice Region (SNP) | VAF 24/223 reads (11%) | catalogued as rs1159440697, COSV53214346; called by muse, mutect2, varscan2
- TPD52L3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs1294329353, COSV58828749; called by muse, mutect2
- TRIM71 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs536248483, COSV67470344; called by muse, mutect2, varscan2
- VSX1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs756519685, COSV65022104; called by muse, mutect2
- XYLB | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs368027581; called by muse, mutect2
- ZMYM3 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1315983707, COSV58738604; called by muse, mutect2
- ZNF250 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs750606892; called by muse, mutect2
- ZNF541 | c.2336C>A p.S779Y | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54546503; called by muse, mutect2, varscan2
- ZNF71 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 58/505 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.072); catalogued as rs1331959865, COSV100046157; called by muse, mutect2, varscan2
- ZNF844 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs779331421; called by muse, mutect2, varscan2
- ABCC12 | c.1760A>G p.N587S | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ACSS2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2
- ADAMTS1 | c.770A>T p.H257L | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALKBH6 | c.533C>T p.T178M (on ENST00000252984 / NM_001297701.2; = p.T206M on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ANHX | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- APCDD1L | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOBEC1 | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- ASIC5 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- C11orf95 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.227); called by muse, mutect2
- C2CD5 | c.50T>A p.V17E | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CAT | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC150 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC197 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- CD70 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CFAP92 | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CHST7 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 35/390 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.08); called by muse, mutect2
- COL11A2 | c.1711G>A p.G571S (on ENST00000341947 / NM_080680.3; = p.G464S on NM_080679.2) | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL9A1 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CXCR5 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYB5D2 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CYFIP1 | c.1490G>C p.R497P | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- CYP2A13 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- CYP2E1 | c.682T>G p.L228V | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.239); called by muse, mutect2
- DLG3 | c.1349C>A p.A450D (on ENST00000374360 / NM_021120.4; = p.A113D on NM_020730.3) | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DNAH17 | c.10285G>A p.A3429T | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP11 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ECHDC2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EGR2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- EVX1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- H2BC12 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- IGBP1P2 | c.468A>C p.Q156H | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGHE | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 39/374 reads (10%) | called by muse, mutect2, varscan2
- IGHE | c.447del p.W149Cfs*69 | Frame Shift Del (DEL) | VAF 32/276 reads (12%) | called by mutect2, pindel*, varscan2
- INSRR | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRS4 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 60/498 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- JADE3 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- LMX1A | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC71 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2
- LRRC9 | c.1585C>A p.Q529K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MAL2 | c.232T>G p.F78V | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MCM10 | c.1627T>C p.S543P (on ENST00000484800 / NM_182751.3; = p.S542P on NM_018518.5) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- MESP2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- METTL18 | c.1061T>G p.I354R | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MFAP3L | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- MRPS35 | c.79T>G p.Y27D | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTA3 | c.1771T>C p.C591R (on ENST00000405094 / NM_001330442.2; = p.C534R on NM_001282755.1) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPW | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODF2 | c.974T>A p.I325K (on ENST00000434106 / NM_153433.2; = p.I301K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- OR8H2 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OTUD7A | c.2003C>T p.A668V (on ENST00000307050 / NM_001382637.1; = p.A661V on NM_130901.3) | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PATL1 | c.1829C>G p.A610G | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDHB3 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.238); called by muse, mutect2
- PCDHGB2 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCLO | c.10570A>G p.I3524V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- PROX1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- PTPRC | c.1346T>A p.L449* | Nonsense Mutation (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- PTPRF | c.4162G>C p.D1388H | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RMND1 | c.401C>G p.T134R | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO2 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPP25L | c.308C>A p.T103K | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEL1L3 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- SEPTIN5 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SGO1 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SHANK1 | c.4732G>C p.E1578Q | Missense Mutation (SNP) | VAF 37/390 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2
- SHROOM2 | c.4633G>A p.A1545T | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SIN3A | c.2771_2774del p.R924Nfs*9 | Frame Shift Del (DEL) | VAF 16/174 reads (9%) | called by mutect2, pindel
- SLC4A10 | c.2885T>C p.F962S (on ENST00000446997 / NM_001354461.2; = p.F932S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SOCS1 | c.34_50del p.A12Rfs*99 | Frame Shift Del (DEL) | VAF 23/254 reads (9%) | called by mutect2, pindel
- SORCS1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2
- SPEF2 | c.3523G>T p.G1175* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- STK32C | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.273); called by muse, mutect2
- SYNCRIP | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TAF11L14 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- TAF1A | c.1037T>G p.I346R | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2
- TCEANC | c.130C>T p.Q44* (on ENST00000380600 / NM_001297563.2; = p.Q74* on NM_152634.4) | Nonsense Mutation (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- TRBV30 | c.121A>C p.T41P | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2
- TTC34 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- UGT1A3 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 34/359 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2
- VPS54 | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- WIZ | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- XAF1 | c.717G>T p.L239F | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.212); called by muse, mutect2
- ZBTB17 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZFPM1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ZNF41 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- ZNF414 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ZNF703 | c.1085C>G p.P362R | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZXDA | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ACTB | c.280C>T p.L94= | Silent (SNP) | VAF 55/451 reads (12%) | catalogued as rs145281194, COSV59318176; ClinVar: likely benign; called by muse, mutect2, varscan2
- AL121899.2 | c.1242C>T p.A414= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs765498791; called by muse, mutect2
- APC | c.5187T>C p.N1729= | Silent (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2
- ARVCF | c.73A>C p.R25= | Silent (SNP) | VAF 36/279 reads (13%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2943C>T p.D981= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as rs375911157; called by muse, mutect2
- ATP2B3 | c.2796C>T p.H932= | Silent (SNP) | VAF 43/373 reads (12%) | catalogued as rs782420658, COSV54844008; called by muse, mutect2, varscan2
- C6 | c.1437T>C p.N479= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 30/358 reads (8%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2
- CARS2 | c.1503G>A p.A501= | Silent (SNP) | VAF 53/385 reads (14%) | catalogued as rs753425826; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC60 | c.72C>T p.A24= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- CFAP46 | c.6033G>T p.P2011= | Silent (SNP) | VAF 40/308 reads (13%) | catalogued as rs775679745; called by muse, mutect2, varscan2
- COL5A2 | c.1557A>T p.G519= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- CRB2 | c.1695G>T p.G565= | Silent (SNP) | VAF 38/319 reads (12%) | called by muse, mutect2, varscan2
- DGAT2 | c.966C>G p.S322= | Silent (SNP) | VAF 27/221 reads (12%) | called by muse, mutect2, varscan2
- DLEU7 | c.111C>T p.P37= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- DMRTA1 | c.453C>T p.S151= | Silent (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2
- ECM2 | c.1962T>G p.A654= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.469C>T p.L157= | Silent (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- EPHB6 | c.2010T>C p.Y670= | Silent (SNP) | VAF 34/426 reads (8%) | called by muse, mutect2
- FAT1 | c.13584G>A p.E4528= | Silent (SNP) | VAF 29/252 reads (12%) | called by muse, mutect2, varscan2
- FER1L5 | c.1632G>A p.P544= (on ENST00000623019; = p.P549= on NM_001293083.2) | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as rs763752174; called by muse, mutect2
- FFAR4 | c.318G>T p.L106= | Silent (SNP) | VAF 32/358 reads (9%) | called by muse, mutect2
- FLG | c.10107A>G p.Q3369= | Silent (SNP) | VAF 31/357 reads (9%) | called by muse, mutect2
- FLVCR2 | c.348C>T p.Y116= | Silent (SNP) | VAF 21/340 reads (6%) | catalogued as rs1426722806, COSV53164094; called by muse, mutect2
- FOXF2 | c.1158C>T p.R386= | Silent (SNP) | VAF 28/292 reads (10%) | catalogued as COSV99453287; called by muse, mutect2
- FOXO6 | c.201G>A p.A67= | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as rs1330825159; called by muse, mutect2, varscan2
- FUOM | c.45G>T p.L15= | Silent (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- GRK5 | c.1575C>T p.N525= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as rs760745107; called by muse, mutect2, varscan2
- GRM1 | c.3456C>T p.R1152= | Silent (SNP) | VAF 40/283 reads (14%) | catalogued as COSV99269028; called by muse, mutect2, varscan2
- GRM3 | c.810C>T p.R270= | Silent (SNP) | VAF 38/364 reads (10%) | catalogued as COSV64480463, COSV64480794; called by muse, mutect2
- GUCA2B | c.273C>T p.T91= | Silent (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- HHIPL1 | c.2076G>A p.V692= | Silent (SNP) | VAF 45/390 reads (12%) | called by muse, mutect2, varscan2
- HOXA3 | c.66C>T p.N22= | Silent (SNP) | VAF 27/393 reads (7%) | catalogued as rs1203782531; called by muse, mutect2
- ICAM5 | c.2712G>A p.A904= | Silent (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- ICE1 | c.5154G>T p.A1718= | Silent (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- KCTD19 | c.948G>A p.L316= | Silent (SNP) | VAF 32/326 reads (10%) | catalogued as rs749744689; called by muse, mutect2
- KRTAP10-1 | c.693C>T p.S231= | Silent (SNP) | VAF 64/637 reads (10%) | catalogued as rs782421332; called by muse, mutect2
- LGR6 | c.99C>T p.T33= | Silent (SNP) | VAF 51/226 reads (23%) | catalogued as rs1220841985; called by muse, mutect2, varscan2
- LVRN | c.120C>T p.C40= | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2, varscan2
- MBOAT7 | c.1161G>A p.L387= | Silent (SNP) | VAF 60/518 reads (12%) | catalogued as rs150838100; called by muse, mutect2, varscan2
- MCF2L | c.1686G>A p.T562= (on ENST00000375608; = p.T530= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/323 reads (12%) | catalogued as rs377733844; called by muse, mutect2, varscan2
- MEX3B | c.1032G>A p.A344= | Silent (SNP) | VAF 42/376 reads (11%) | catalogued as rs781410998, COSV61662735, COSV61662993; called by mutect2, varscan2
- MGMT | c.240C>T p.P80= (on ENST00000306010; = p.P49= on NM_002412.5) | Silent (SNP) | VAF 38/343 reads (11%) | catalogued as rs756591584, COSV100024358, COSV60036759; called by muse, mutect2
- MTCL1 | c.847C>A p.R283= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as rs1267905252; called by muse, mutect2, varscan2
- MYO18A | c.651C>T p.T217= | Silent (SNP) | VAF 35/283 reads (12%) | called by muse, mutect2, varscan2
- NID1 | c.1860C>T p.H620= | Silent (SNP) | VAF 14/256 reads (5%) | catalogued as rs374028475, COSV51625385; called by muse, mutect2
- NINL | c.2679C>T p.P893= | Silent (SNP) | VAF 38/309 reads (12%) | catalogued as rs763227385, COSV53999556; called by muse, mutect2, varscan2
- NKX2-1 | c.360G>A p.P120= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as rs916454388; called by muse, mutect2, varscan2
- NKX2-4 | c.756G>A p.A252= | Silent (SNP) | VAF 36/374 reads (10%) | catalogued as rs1362692948, COSV100698582; called by muse, mutect2, varscan2
- NPBWR2 | c.558C>T p.G186= | Silent (SNP) | VAF 48/526 reads (9%) | catalogued as rs368497080; called by muse, mutect2
- OTUD6A | c.228C>T p.V76= | Silent (SNP) | VAF 70/498 reads (14%) | catalogued as rs1341015160, COSV57972680; called by muse, mutect2, varscan2
- PCDH10 | c.963C>T p.S321= | Silent (SNP) | VAF 34/321 reads (11%) | catalogued as rs1360367795, COSV52091189, COSV52101149; called by muse, mutect2, varscan2
- PCDH15 | c.5052G>A p.A1684= (on ENST00000644397 / NM_001354429.2; = p.A1626= on NM_001142771.2) | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs572313030, COSV64722171; called by muse, mutect2, varscan2
- PCDHAC2 | c.399C>T p.A133= | Silent (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2, varscan2
- PHYHIPL | c.12G>A p.P4= | Silent (SNP) | VAF 26/233 reads (11%) | called by muse, mutect2, varscan2
- PIN4 | c.111G>A p.A37= (on ENST00000664196; = p.A12= on NM_006223.4) | Silent (SNP) | VAF 33/299 reads (11%) | called by muse, mutect2, varscan2
- PLA2G10 | c.439T>C p.L147= | Silent (SNP) | VAF 32/346 reads (9%) | called by muse, mutect2
- PNMA6F | c.57C>T p.I19= | Silent (SNP) | VAF 50/411 reads (12%) | called by muse, mutect2, varscan2
- PRR18 | c.354C>T p.A118= | Silent (SNP) | VAF 35/291 reads (12%) | catalogued as rs1260399966; called by muse, mutect2, varscan2
- PTCHD4 | c.33G>A p.A11= | Silent (SNP) | VAF 18/292 reads (6%) | catalogued as rs753515083; called by muse, mutect2
- REPS2 | c.24G>A p.A8= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs1286992068; called by muse, mutect2, varscan2
- RXFP3 | c.963G>A p.L321= | Silent (SNP) | VAF 41/415 reads (10%) | called by muse, mutect2, varscan2
- SLC27A1 | c.1923G>A p.S641= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs565994088, COSV99393586; called by muse, mutect2
- SPAG1 | c.132C>T p.C44= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs376986262; ClinVar: likely benign; called by muse, mutect2
- ST6GALNAC3 | c.441G>A p.A147= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs779081271, COSV60348149; called by muse, mutect2, varscan2
- STAB1 | c.7386C>T p.P2462= | Silent (SNP) | VAF 32/267 reads (12%) | called by muse, mutect2, varscan2
- STON2 | c.651C>A p.R217= | Silent (SNP) | VAF 41/329 reads (12%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.2592G>A p.A864= | Silent (SNP) | VAF 61/417 reads (15%) | catalogued as rs989713108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX55 | c.768A>T p.V256= | Silent (SNP) | VAF 35/309 reads (11%) | called by muse, mutect2, varscan2
- TMC2 | c.267C>T p.G89= | Silent (SNP) | VAF 26/334 reads (8%) | catalogued as COSV100727504; called by muse, mutect2
- TRPC6 | c.1677C>T p.D559= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs552837414, COSV60259616; ClinVar: benign; called by muse, mutect2
- TSPYL6 | c.258G>A p.A86= | Silent (SNP) | VAF 41/297 reads (14%) | catalogued as rs374633280; called by muse, mutect2, varscan2
- USH2A | c.12621C>T p.A4207= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs369544099, COSV56325711; called by muse, mutect2
- VPREB1 | c.78G>A p.P26= | Silent (SNP) | VAF 21/247 reads (9%) | catalogued as rs773875100, COSV56425979; called by muse, mutect2
- ZC3H12B | c.2196G>A p.P732= | Silent (SNP) | VAF 27/248 reads (11%) | catalogued as rs747943213, COSV59046222; called by muse, varscan2
- ZNF546 | c.234C>T p.D78= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs760436332, COSV61258452; called by muse, mutect2
- ZNF76 | c.24G>A p.T8= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as rs1169830945, COSV57591031; called by muse, mutect2
- ZNF783 | c.135G>A p.T45= | Silent (SNP) | VAF 44/454 reads (10%) | catalogued as rs766903514, COSV65185202; called by muse, mutect2
- ZNF787 | c.375G>A p.L125= | Silent (SNP) | VAF 85/584 reads (15%) | called by muse, mutect2, varscan2
- ZNRF3 | c.1287C>G p.A429= (on ENST00000544604 / NM_001206998.2; = p.A329= on NM_032173.3) | Silent (SNP) | VAF 34/326 reads (10%) | called by muse, mutect2, varscan2
- ZYG11A | c.2214T>C p.I738= | Silent (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2, varscan2
- AC005165.1 | n.460A>G | RNA (SNP) | VAF 8/92 reads (9%) | catalogued as rs1426631895; called by muse, mutect2
- AC010186.2 | chr12:9647861 G>A | 5'Flank (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- AC011416.3 | chr5:127229717 C>T | 5'Flank (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- AL161938.1 | n.158C>T | RNA (SNP) | VAF 33/346 reads (10%) | called by muse, mutect2
- FHL2 | chr2:105399257 C>T | 5'Flank (SNP) | VAF 28/240 reads (12%) | catalogued as rs969938524; called by muse, varscan2
- KCNC4 | c.*18G>A | 3'UTR (SNP) | VAF 31/316 reads (10%) | catalogued as rs532060416; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421123T>G | Intron (SNP) | VAF 16/200 reads (8%) | catalogued as rs1314528747; called by muse, mutect2
- LINC02693 | n.863C>G | RNA (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2, varscan2
- MALT1 | c.-89G>A | 5'UTR (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- NKX2-1 | c.-9C>T | 5'UTR (SNP) | VAF 8/188 reads (4%) | catalogued as COSV61390749; called by muse, mutect2
- PRPF40B | c.-63T>C | 5'UTR (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- RAB35 | c.*265G>A | 3'UTR (SNP) | VAF 28/305 reads (9%) | catalogued as rs1461409756; called by muse, mutect2
- RALA | c.-231G>T | 5'UTR (SNP) | VAF 24/184 reads (13%) | called by muse, varscan2
- RHD | c.*51T>C | 3'UTR (SNP) | VAF 31/300 reads (10%) | called by muse, mutect2, varscan2
- SMOC2 | c.*1116A>T | 3'UTR (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- SNU13 | chr22:41693681 C>T | 5'Flank (SNP) | VAF 48/367 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.864G>A | RNA (SNP) | VAF 24/221 reads (11%) | catalogued as COSV50486265; called by muse, mutect2, varscan2
- ST3GAL3 | c.1083+724C>T | Intron (SNP) | VAF 34/286 reads (12%) | called by mutect2, varscan2
- TCF4 | c.305-153A>C | Intron (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- TCHHL1 | chr1:152079816 G>A | 3'Flank (SNP) | VAF 29/240 reads (12%) | called by muse, mutect2, varscan2
- ZNF516 | chr18:76496590 G>A | 5'Flank (SNP) | VAF 9/58 reads (16%) | catalogued as rs1259236679; called by muse, mutect2
